Somatic mutation profile of tumor specimen TCGA-FS-A1ZP-06A (aliquot TCGA-FS-A1ZP-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.4 years (19,864 days).
Specimen TCGA-FS-A1ZP-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37788a7c-e382-4ce3-824d-97a04cf12f93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZP-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZP-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e246b9b9-ddac-46ce-baba-ed13871e8131

The open-access MAF lists 498 somatic variants for this specimen: 319 protein-altering or splice-affecting, 170 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 170, Nonsense Mutation 22, Splice Site 5, Intron 5, Splice Region 3, Translation Start Site 3, RNA 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2C8 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV64876218; called by muse, mutect2, varscan2
- GJA8 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 127/196 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1114167310, COSV53787950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 50/136 reads (37%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAH | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs62508739, CM040236, COSV61014382; ClinVar: pathogenic / not provided; called by mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 45/126 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.5285G>A p.G1762E (on ENST00000303395 / NM_001202435.3; = p.G1751E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917950, CM067008, COSV57662232, COSV57678098; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773877956, COSV52704325; called by muse, mutect2, varscan2
- ABCA13 | c.10400C>T p.S3467F | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs763985029, COSV71283671; called by muse, mutect2, varscan2
- ABCA6 | c.4286G>A p.G1429E | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52636294; called by muse, mutect2, varscan2
- ABCC10 | c.2980C>T p.L994F (on ENST00000372530 / NM_001198934.2; = p.L966F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs777367706, COSV55084992; called by muse, varscan2
- ABCC9 | c.4408C>T p.L1470F | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.248); catalogued as COSV53963987; called by muse, varscan2
- ABCF3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770951242, COSV53051574; called by mutect2, varscan2
- ADAM29 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63660962; called by muse, mutect2, varscan2
- ADAM29 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV63660973; called by muse, mutect2, varscan2
- ADAMTS16 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV56980237; called by mutect2, varscan2
- ADAMTS20 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV67127677; called by mutect2, varscan2
- ADAMTS20 | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67127693; called by muse, mutect2, varscan2
- ADGRF5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs865878654, COSV51930489; called by mutect2, varscan2
- ADGRG4 | c.6938G>A p.R2313K | Missense Mutation (SNP) | VAF 94/120 reads (78%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1468956889, COSV54950764; called by muse, mutect2, varscan2
- ADGRL3 | c.3596G>A p.R1199Q (on ENST00000506720 / NM_001322402.2; = p.R1131Q on NM_015236.6) | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.588); catalogued as rs760531521, COSV72229589; called by muse, mutect2, varscan2
- AGXT2 | c.579C>T p.F193= | Splice Region (SNP) | VAF 54/164 reads (33%) | catalogued as COSV51484284; called by mutect2, varscan2
- AK7 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs368876091, COSV50869385; called by mutect2, varscan2
- ALG2 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53058842; called by muse, mutect2, varscan2
- ALPK2 | c.3146C>T p.S1049F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV64490625; called by muse, mutect2, varscan2
- ANK2 | c.6383C>T p.P2128L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52148607; called by muse, mutect2, varscan2
- ANK3 | c.6797G>A p.R2266K | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.754); catalogued as rs1277783590, COSV55046858; called by muse, mutect2, varscan2
- ARHGAP30 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs766260516, COSV63515080; called by mutect2, varscan2
- ARID2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57596424; called by muse, mutect2, varscan2
- ASB18 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV58232649; called by muse, mutect2, varscan2
- ASXL3 | c.4352G>A p.G1451E | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV52458860; called by muse, mutect2, varscan2
- ASXL3 | c.5738T>C p.V1913A | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); catalogued as rs1433597886, COSV52458867; called by muse, mutect2, varscan2
- ATP13A5 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.41); catalogued as COSV60866407; called by muse, mutect2, varscan2
- ATRNL1 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58075816; called by muse, mutect2, varscan2
- ATRX | c.6457C>T p.R2153C | Missense Mutation (SNP) | VAF 63/79 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64872312, COSV64880905; called by mutect2, varscan2
- BCHE | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52254080; called by muse, mutect2, varscan2
- BICC1 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54062215; called by muse, mutect2, varscan2
- BICC1 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54062223; called by muse, mutect2, varscan2
- BICC1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV54062236, COSV54065999; called by muse, mutect2, varscan2
- BICD2 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377454040; called by mutect2, varscan2
- BRCA1 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV58785052; called by muse, mutect2, varscan2
- BTNL9 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV59793825; called by muse, mutect2, varscan2
- C9 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749534250, COSV54674594; called by mutect2, varscan2
- CACNA1E | c.6638C>T p.S2213F (on ENST00000367573 / NM_001205293.3; = p.S2170F on NM_000721.4) | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.305); catalogued as COSV62384003, COSV62412863; called by muse, mutect2, varscan2
- CALCRL | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201789608, COSV66473826; called by mutect2, varscan2
- CASP7 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.877); catalogued as COSV61881183; called by muse, mutect2, varscan2
- CCDC170 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV53337121; called by muse, mutect2, varscan2
- CCDC178 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV100285616, COSV55761980; called by muse, mutect2, varscan2
- CCDC57 | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.4); PolyPhen benign (0.403); catalogued as rs1375833473, COSV66432902; called by muse, mutect2, varscan2
- CCT8L2 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63461736; called by muse, mutect2, varscan2
- CD22 | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs1258852415, COSV50049824; called by muse, mutect2, varscan2
- CECR2 | c.1850C>T p.P617L (on ENST00000342247 / NM_001290047.2; = p.P434L on NM_001290046.1) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV52837195; called by muse, mutect2, varscan2
- CFAP58 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs777981562, COSV63832819; called by muse, mutect2, varscan2
- CFTR | c.3823G>A p.D1275N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50042333; called by muse, mutect2, varscan2
- CHAMP1 | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63521864; called by muse, varscan2
- CHAT | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs202059535; called by mutect2, varscan2
- CHL1 | c.1573C>T p.R525C (on ENST00000397491 / NM_001253387.1; = p.R541C on NM_006614.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs765675947, COSV56587685; called by mutect2, varscan2
- CLCA4 | c.2396A>T p.D799V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV65282600; called by muse, mutect2, varscan2
- CLEC3A | c.205G>A p.E69K (on ENST00000651443; = p.E60K on NM_005752.6) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55219916; called by mutect2, varscan2
- CLEC4C | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV63582651, COSV63583304; called by muse, mutect2, varscan2
- CLYBL | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779345907, COSV59216188, COSV59217681; called by muse, mutect2, varscan2
- CNTN4 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV61868793; called by muse, mutect2, varscan2
- CNTN5 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54285909; called by muse, mutect2, varscan2
- COL24A1 | c.4589G>A p.S1530N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs183004053, COSV65302706; called by muse, mutect2, varscan2
- CPLANE1 | c.9251C>T p.P3084L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs747597826, COSV57053908; called by muse, varscan2
- CRTC3 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 567/767 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV51594546; called by muse, mutect2, varscan2
- CTSH | c.101A>T p.H34L | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54984277; called by muse, mutect2, varscan2
- CTSV | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52344121; called by muse, mutect2, varscan2
- CYP2C8 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV64876222; called by mutect2, varscan2
- CYP2E1 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53312455, COSV53313774; called by muse, mutect2, varscan2
- CYP4A22 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774220009, COSV53738529; called by muse, mutect2, varscan2
- CYP4Z1 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs564652252, COSV61963946; called by mutect2, varscan2
- DBF4B | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as COSV59259225; called by muse, mutect2, varscan2
- DCAF6 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV56575576; called by muse, mutect2, varscan2
- DGKI | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as rs371173102; called by mutect2, varscan2
- DLAT | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs781951438, COSV54769256; called by muse, mutect2, varscan2
- DLGAP4 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.056); catalogued as COSV59414985; called by muse, varscan2
- DNAH17 | c.4447G>A p.D1483N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750391; called by muse, mutect2, varscan2
- DNAH5 | c.9095C>T p.S3032L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as CM147992, COSV54202804; called by mutect2, varscan2
- DNMBP | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60621311; called by muse, mutect2, varscan2
- DOCK10 | c.5300C>T p.P1767L | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV51352503; called by muse, mutect2, varscan2
- DOCK3 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV56506188; called by muse, mutect2, varscan2
- DPYD | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV64591966; called by muse, mutect2, varscan2
- DSG1 | c.3106C>T p.R1036* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs144199555, COSV57140237; called by mutect2, varscan2
- EBF3 | c.1723C>T p.P575S (on ENST00000355311 / NM_001375392.1; = p.P530S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs764680863, COSV62471985; called by muse, mutect2, varscan2
- EGFL6 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182977902, COSV63632763; called by muse, mutect2, varscan2
- EPHA6 | c.2083C>T p.P695S (on ENST00000389672 / NM_001080448.3; = p.P87S on NM_173655.4) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV101063221, COSV67561294; called by muse, mutect2, varscan2
- ESR2 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50828861; called by muse, mutect2, varscan2
- EYA2 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57939267; called by mutect2, varscan2
- F2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61314897; called by muse, mutect2, varscan2
- FAM110B | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.309); catalogued as COSV64063710; called by muse, mutect2, varscan2
- FAM13C | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431276508, COSV53244064; called by mutect2, varscan2
- FANCD2OS | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as COSV55033782; called by muse, mutect2, varscan2
- FASN | c.5533C>T p.Q1845* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as rs1349916698, COSV60751108; called by muse, mutect2, varscan2
- FBLIM1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.766); catalogued as COSV60028855; called by muse, mutect2, varscan2
- FCRL4 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 90/119 reads (76%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs145332965, COSV54860169; called by muse, mutect2, varscan2
- FCRL5 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as rs529674464, COSV62512034; called by muse, mutect2, varscan2
- FGD2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs779517528, COSV51462501; called by muse, varscan2
- FGF6 | c.450+1G>A p.X150_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV57403562; called by muse, mutect2
- FH | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs1200934499, COSV63817618; called by muse, mutect2, varscan2
- FHDC1 | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52598082; called by muse, mutect2, varscan2
- FLG | c.11902G>A p.G3968S | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV64237667; called by muse, mutect2, varscan2
- FMOD | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 105/167 reads (63%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as COSV61609694; called by muse, mutect2, varscan2
- FPR2 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV60672050; called by muse, mutect2, varscan2
- FRMPD2 | c.2220G>A p.M740I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59715724; called by mutect2, varscan2
- G6PC | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750470654, CM980783, COSV53830216, COSV53831745; called by mutect2, varscan2
- GABRA6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377669113; called by muse, mutect2, varscan2
- GABRB1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV54972666; called by muse, mutect2, varscan2
- GAP43 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV59342793; called by muse, mutect2, varscan2
- GIMAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56234584; called by muse, mutect2, varscan2
- GIMAP6 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV61032627; called by muse, mutect2, varscan2
- GLIS3 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV67941757; called by muse, mutect2, varscan2
- GPM6A | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54534164, COSV99704812; called by muse, mutect2, varscan2
- GPRC5A | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs889364047, COSV50007354; called by mutect2, varscan2
- GRIN2A | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100407879, COSV58022699; called by muse, mutect2, varscan2
- GRM3 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as COSV64467928; called by muse, mutect2, varscan2
- GRP | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56879145; called by muse, mutect2, varscan2
- HAO2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as rs775135179, COSV58038114; called by mutect2, varscan2
- HERC1 | c.3206C>T p.S1069F | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV71246278; called by muse, mutect2, varscan2
- HIVEP1 | c.3032T>C p.L1011P | Missense Mutation (SNP) | VAF 181/272 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65099192; called by muse, mutect2, varscan2
- HOXD4 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV60459357; called by muse, mutect2, varscan2
- HSPA5 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.006); catalogued as rs774479903, COSV61028673; called by muse, mutect2, varscan2
- IDO1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV53713179; called by muse, mutect2
- IL10 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV65594381; called by mutect2, varscan2
- INPP5D | c.2021G>A p.R674Q (on ENST00000445964 / NM_001017915.3; = p.R673Q on NM_005541.5) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64035697; called by muse, mutect2, varscan2
- JAKMIP1 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV51523338; called by muse, mutect2, varscan2
- KANSL1 | c.2683C>T p.Q895* (on ENST00000574590 / NM_001193465.2; = p.Q896* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs143533965, COSV52265562; called by mutect2, varscan2
- KCNH5 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.118); catalogued as COSV59753831; called by muse, mutect2, varscan2
- KCNQ1 | c.1033-1G>A p.X345_splice | Splice Site (SNP) | VAF 48/160 reads (30%) | catalogued as CS129985, COSV50101129; called by muse, mutect2
- KCNQ1 | c.1034G>C p.G345A | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM144634, CM1511176, CM960905, COSV50101145; called by muse, mutect2
- KIAA1109 | c.12382C>T p.R4128* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | catalogued as rs1305380775, COSV52664128; called by muse, mutect2, varscan2
- KIF6 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.018); catalogued as COSV54668654; called by mutect2, varscan2
- KLHDC8A | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as rs149498417; called by muse, varscan2
- KLHL14 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.982); catalogued as COSV63830352; called by mutect2, varscan2
- KLHL26 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1008222780, COSV56316446; called by muse, mutect2, varscan2
- KLHL40 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs771203108, COSV55132986, COSV55137444; called by mutect2, varscan2
- KPRP | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs267598039, COSV64221095, COSV64221244; called by muse, mutect2, varscan2
- L3MBTL4 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs756773510, COSV53114611; called by muse, varscan2
- LAMA3 | c.8642C>T p.S2881F (on ENST00000313654 / NM_198129.4; = p.S1272F on NM_000227.6) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV52530651; called by muse, mutect2, varscan2
- LRBA | c.6739C>T p.P2247S | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334633442, COSV63950657; called by muse, mutect2, varscan2
- LRFN2 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57824375; called by mutect2, varscan2
- LRFN2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57824381; called by muse, mutect2, varscan2
- LRP1B | c.4895G>A p.R1632Q | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777763232, COSV67191741; called by mutect2, varscan2
- LRP1B | c.4363G>A p.D1455N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67191744; called by muse, mutect2, varscan2
- LTBP1 | c.1418G>A p.G473E (on ENST00000404816 / NM_206943.4; = p.G147E on NM_000627.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs745306877, COSV63181215; called by muse, mutect2, varscan2
- MACF1 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 71/188 reads (38%) | catalogued as COSV58362274; called by muse, varscan2
- MACROD2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs867413234, COSV53951516; called by muse, mutect2, varscan2
- MAGEA1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 62/67 reads (93%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs782043198, COSV63118283; called by muse, mutect2, varscan2
- MAST1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV52241978; called by mutect2, varscan2
- MATK | c.958G>A p.G320S (on ENST00000310132 / NM_139355.3; = p.G321S on NM_002378.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV100035968; called by muse, varscan2
- MATN4 | c.1277G>A p.G426E (on ENST00000372754; = p.G385E on NM_003833.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | PolyPhen probably damaging (1); catalogued as rs1178429274, COSV61350489; called by muse, mutect2, varscan2
- MCHR2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56000200; called by muse, mutect2, varscan2
- MED12L | c.4864C>T p.R1622* | Nonsense Mutation (SNP) | VAF 58/192 reads (30%) | catalogued as rs765363421, COSV56370281; called by mutect2, varscan2
- MERTK | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147779020, COSV54925189, COSV54925205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MET | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752842662, COSV59257593; ClinVar: uncertain significance; called by mutect2, varscan2
- MICAL2 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV56317177; called by muse, mutect2, varscan2
- MKI67 | c.5464C>T p.R1822C | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs750568118, COSV64072852; called by mutect2, varscan2
- MOCS3 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777111395, COSV54865676; called by muse, mutect2, varscan2
- MRGPRX1 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.182); catalogued as COSV57106117; called by muse, mutect2, varscan2
- MRPL32 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs531271105, COSV56237150; called by mutect2, varscan2
- MUC16 | c.17876C>T p.S5959F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV67448919; called by muse, mutect2, varscan2
- MUC16 | c.16868C>T p.P5623L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); catalogued as rs368020997, COSV67448929, COSV67460035; called by muse, mutect2, varscan2
- MYH4 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs569210501, COSV55113362; called by muse, mutect2, varscan2
- MYL2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs727504405, COSV57406212, COSV57408315; called by mutect2, varscan2
- MYLK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs564792567, COSV60604501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK3 | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV67362744; called by muse, mutect2, varscan2
- MYT1L | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV67710462; called by muse, mutect2, varscan2
- NAALAD2 | c.194+1G>A p.X65_splice | Splice Site (SNP) | VAF 19/36 reads (53%) | catalogued as COSV58959123; called by muse, mutect2, varscan2
- NALCN | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV51920841; called by mutect2, varscan2
- NEB | c.6021G>T p.M2007I | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV50829105; called by muse, mutect2, varscan2
- NFASC | c.3541A>C p.T1181P (on ENST00000339876 / NM_001378329.1; = p.T1110P on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/185 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58360232; called by muse, mutect2, varscan2
- NLRP4 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV56708952; called by muse, mutect2, varscan2
- NOL4 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as COSV52340503; called by muse, mutect2, varscan2
- NOL8 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs749823093, COSV62634305; called by mutect2, varscan2
- NOS1 | c.2370G>A p.V790= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as rs757093415, COSV57607805; called by mutect2, varscan2
- NOS2 | c.2320G>A p.G774R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58222185; called by muse, mutect2, varscan2
- NOTCH4 | c.2300G>A p.S767N | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66679083; called by muse, mutect2, varscan2
- OLFML2A | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.154); catalogued as COSV56582141; called by muse, mutect2, varscan2
- OPRK1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.058); catalogued as COSV55568678; called by muse, mutect2, varscan2
- OR10J5 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs763976151, COSV100604792, COSV58385040; called by mutect2, varscan2
- OR10V1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as rs1565148088, COSV55695395; called by mutect2, varscan2
- OR2H1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1376282042, COSV65810257; called by muse, mutect2, varscan2
- OR4E2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs369264275; called by mutect2, varscan2
- OR4L1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs553802462, COSV59849023; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, varscan2
- OR51B4 | c.788A>T p.K263I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66516878; called by mutect2, varscan2
- OR52E2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs983458453, COSV58611949; called by muse, mutect2, varscan2
- OR52E4 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57624056; called by muse, mutect2, varscan2
- OR56B4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs866651182, COSV57204093; called by muse, mutect2, varscan2
- OR5V1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65826621; called by muse, varscan2
- OR7C2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as COSV50180284; called by muse, mutect2, varscan2
- PARM1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as rs906221539, COSV56650702; called by muse, mutect2, varscan2
- PCDHB13 | c.2282C>T p.T761I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as COSV53393719; called by muse, varscan2
- PCDHB7 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.02); catalogued as rs1267808278, COSV50755510, COSV99176927; called by muse, mutect2, varscan2
- PCDHGA8 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.192); catalogued as rs1356713892; called by muse, mutect2, varscan2
- PCLO | c.6098C>T p.S2033F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs938415119, COSV61618905; called by muse, mutect2, varscan2
- PCLO | c.4573C>T p.P1525S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61618922; called by muse, mutect2, varscan2
- PCNX2 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50784020; called by mutect2, varscan2
- PDE2A | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as COSV57803230; called by muse, mutect2, varscan2
- PDE8B | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs200873122, COSV53732903; called by muse, mutect2, varscan2
- PEG3 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55626696; called by muse, mutect2, varscan2
- PHACTR4 | c.190+2T>G p.X64_splice (on ENST00000373839 / NM_001350159.2; = p.X74_splice on NM_023923.4) | Splice Site (SNP) | VAF 25/75 reads (33%) | catalogued as COSV65783264; called by muse, mutect2, varscan2
- PIWIL4 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54408000; called by muse, mutect2, varscan2
- PKHD1L1 | c.7766A>G p.N2589S | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV65738464; called by muse, mutect2, varscan2
- PLA2G7 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51258599; called by mutect2, varscan2
- POLR2B | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as COSV58898869; called by mutect2, varscan2
- POT1 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62928299; called by mutect2, varscan2
- POTEF | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as COSV62540046; called by muse, mutect2, varscan2
- PPIP5K2 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs782492973, COSV58602332; called by mutect2, varscan2
- PRAG1 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as rs770055358, COSV58158009; called by muse, mutect2, varscan2
- PRAMEF2 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 102/252 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV53572911, COSV53580169; called by muse, mutect2, varscan2
- PRKAR2B | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55922733, COSV55926098; called by muse, mutect2, varscan2
- PROX1 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 112/155 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0.061); catalogued as COSV54776371; called by muse, mutect2, varscan2
- PRPSAP2 | c.632A>T p.H211L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV52064595; called by muse, mutect2, varscan2
- PRSS38 | c.811A>G p.N271D | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV64539761; called by muse, mutect2, varscan2
- PSG7 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.373); catalogued as rs151272638, COSV68444408; called by muse, mutect2, varscan2
- PTGER3 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV60688373, COSV60692222; called by mutect2, varscan2
- PTGS1 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV56290421; called by muse, mutect2, varscan2
- PTPRN2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV67024965; called by muse, mutect2, varscan2
- RAD51AP2 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs758741895, COSV67587448; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54572505; called by muse, varscan2
- RBBP6 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs1255790337, COSV60503618; called by muse, varscan2
- RBFOX1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60947948; called by muse, mutect2, varscan2
- RBPJ | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 72/186 reads (39%) | catalogued as COSV60749298, COSV60755088; called by mutect2, varscan2
- RIMKLA | c.175A>G p.N59D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.05); catalogued as COSV69815237; called by muse, mutect2, varscan2
- RPGRIP1 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52845982; called by muse, mutect2, varscan2
- RRN3 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52213437; called by muse, varscan2
- RSAD2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65908020; called by muse, mutect2, varscan2
- RUNX3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV58242773; called by muse, varscan2
- RXFP1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57047279; called by muse, mutect2, varscan2
- SALL4 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV53850208; called by muse, mutect2, varscan2
- SAMD9L | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59079979; called by muse, mutect2, varscan2
- SAMSN1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53468236, COSV99581182; called by muse, mutect2, varscan2
- SAP30 | c.331A>T p.I111L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56634574; called by muse, mutect2, varscan2
- SCN11A | c.3137G>A p.R1046Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147061364; ClinVar: uncertain significance; called by muse, varscan2
- SCN1A | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs148371904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK2 | c.1099A>T p.I367F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV66182129; called by mutect2, varscan2
- SEMA3A | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751308898, COSV54863069; called by mutect2, varscan2
- SERINC2 | c.955T>G p.W319G (on ENST00000373709 / NM_178865.5; = p.W323G on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65489502; called by muse, mutect2, varscan2
- SETBP1 | c.3764C>T p.P1255L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV56314390, COSV56317179; called by muse, varscan2
- SGIP1 | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52763872; called by muse, mutect2, varscan2
- SHTN1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs772447430, COSV53380035; called by mutect2, varscan2
- SIGLEC5 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs192335508, COSV55777872; called by mutect2, varscan2
- SIRPB1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV53537699; called by muse, mutect2, varscan2
- SLC13A3 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51712281; called by muse, mutect2, varscan2
- SLC16A12 | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV57947887; called by mutect2, varscan2
- SLC27A6 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV52479923; called by mutect2, varscan2
- SLC40A1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53722048; called by muse, mutect2, varscan2
- SLIT2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56562221; called by muse, varscan2
- SLIT2 | c.1904T>A p.L635H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56562227; called by mutect2, varscan2
- SNAP25 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV54770818; called by muse, mutect2, varscan2
- SNURF | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.322); catalogued as COSV57594471; called by muse, mutect2, varscan2
- SORL1 | c.6603G>A p.M2201I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV52750214; called by mutect2, varscan2
- SPAG17 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV60453829; called by mutect2, varscan2
- SPANXN2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 90/117 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV65127784; called by muse, varscan2
- SPARCL1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV56802547; called by muse, mutect2, varscan2
- SPEF2 | c.3093G>A p.W1031* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV61553312; called by muse, mutect2, varscan2
- SPINK5 | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56249707; called by muse, mutect2, varscan2
- SPNS3 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61069257; called by muse, mutect2, varscan2
- SPOCK3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.091); catalogued as rs1422436706, COSV62718113; called by mutect2, varscan2
- SYNE2 | c.19312C>T p.P6438S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV59941417; called by muse, mutect2
- SYTL1 | c.664G>A p.G222R (on ENST00000543823; = p.G210R on NM_032872.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV58870449; called by mutect2, varscan2
- SYTL5 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52898842; called by muse, mutect2, varscan2
- TBC1D8 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV65210208; called by muse, varscan2
- TBC1D9 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs756151069, COSV71306981; called by mutect2, varscan2
- TCF20 | c.4709C>T p.S1570F | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.212); catalogued as COSV59488809; called by muse, varscan2
- TERB2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV61650558; called by muse, mutect2, varscan2
- TFF2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757931974, COSV52295740, COSV99367174; called by mutect2, varscan2
- TGM4 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56092923; called by muse, mutect2, varscan2
- THBS1 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 38/109 reads (35%) | catalogued as COSV52950379; called by muse, varscan2
- THSD7B | c.4340G>A p.R1447Q (on ENST00000272643; = p.R1445Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267598902, COSV55651965; called by mutect2, varscan2
- TLN1 | c.3968C>T p.S1323F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59204690; called by muse, mutect2, varscan2
- TLR4 | c.1036C>T p.P346S (on ENST00000355622 / NM_138554.5; = p.P306S on NM_003266.4) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62922563; called by muse, mutect2, varscan2
- TMPRSS11B | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs561180941, COSV60291465; called by mutect2, varscan2
- TNS3 | c.474-2A>G p.X158_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV60787500; called by mutect2, varscan2
- TOX | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV63843078; called by muse, mutect2
- TPO | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV61096163; called by mutect2, varscan2
- TPTE | c.1138G>A p.E380K (on ENST00000618007 / NM_199261.4; = p.E362K on NM_199259.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs781489069; called by mutect2, varscan2
- TRERF1 | c.2807G>A p.R936Q | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs777625510, COSV61667773; called by muse, varscan2
- TRHDE | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs1306640866, COSV53835012; called by mutect2, varscan2
- TRIM27 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 55/78 reads (71%) | catalogued as COSV65873317; called by muse, mutect2, varscan2
- TSPAN5 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV59874163; called by muse, mutect2, varscan2
- TTN | c.78634G>A p.E26212K (on ENST00000591111; = p.E18788K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | PolyPhen benign (0.081); catalogued as COSV59912250; called by muse, mutect2, varscan2
- USP6 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51476022, COSV51476667; called by muse, mutect2, varscan2
- VARS1 | c.2396C>T p.S799F | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63304264; called by muse, mutect2, varscan2
- VSX2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs551394732, COSV56216725; called by muse, mutect2, varscan2
- VWA7 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 77/436 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs760103923, COSV65172596, COSV65173655; called by muse, mutect2, varscan2
- WDR49 | c.1762G>A p.E588K (on ENST00000308378 / NM_001366158.1; = p.E929K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV57702820; called by muse, mutect2, varscan2
- WDR70 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54267693; called by muse, varscan2
- WDR72 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV64742258, COSV64752288; called by mutect2, varscan2
- WFS1 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs777508919, CM043877, COSV56987716; called by muse, mutect2, varscan2
- WNT9B | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.412); catalogued as COSV51517575; called by mutect2, varscan2
- XDH | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs558003041, COSV65147237, COSV65151842; called by mutect2, varscan2
- XYLT1 | c.2432C>A p.P811H | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54478721; called by muse, mutect2, varscan2
- ZBBX | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs199795579; called by muse, mutect2, varscan2
- ZBED9 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV71729208; called by muse, varscan2
- ZBTB11 | c.1819C>T p.Q607* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | catalogued as COSV57244166; called by muse, varscan2
- ZFC3H1 | c.5365C>T p.L1789F | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66430567; called by muse, mutect2, varscan2
- ZFHX4 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV50537102; called by muse, mutect2, varscan2
- ZFP57 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); catalogued as COSV65305752; called by muse, mutect2, varscan2
- ZNF343 | c.1691T>A p.L564H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53852932; called by muse, mutect2, varscan2
- ZNF358 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV51174152; called by muse, mutect2
- ZNF410 | c.36C>T p.L12= | Splice Region (SNP) | VAF 31/73 reads (42%) | catalogued as COSV57910038; called by muse, mutect2, varscan2
- ZNF446 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1374701767, COSV52179797; called by muse, mutect2, varscan2
- ZNF500 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1427550372; called by mutect2, varscan2
- ZNF500 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs771704907; called by muse, mutect2, varscan2
- ZP4 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as rs371096907; called by muse, mutect2, varscan2
- ZSCAN5A | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.412); catalogued as COSV99570235; called by mutect2, varscan2
- ZSCAN5B | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1163381663, COSV61999301; called by muse, mutect2, varscan2
- ZYG11B | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53750480; called by muse, mutect2, varscan2
- BCL6 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- COL24A1 | c.3515G>A p.R1172K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2
- GLRB | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- KMT2B | c.4678C>T p.P1560S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBPF26 | c.3337G>A p.E1113K (on ENST00000620612; = p.E851K on NM_001351372.1) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); called by muse, mutect2
- NLRP12 | c.1954T>C p.F652L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPEF2 | c.3092G>A p.W1031* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | called by mutect2, varscan2
- TPTE | c.1574G>A p.R525K (on ENST00000618007 / NM_199261.4; = p.R507K on NM_199259.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- A4GALT | c.243C>T p.F81= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as CD022513, COSV50744066; called by muse, mutect2, varscan2
- ADAMDEC1 | c.897G>A p.G299= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs141164035, COSV56474281, COSV56476253; called by muse, varscan2
- ADAMTS17 | c.2325A>G p.G775= | Silent (SNP) | VAF 56/499 reads (11%) | catalogued as COSV51474289; called by muse, mutect2, varscan2
- ADGRF4 | c.1353G>A p.L451= | Silent (SNP) | VAF 44/274 reads (16%) | catalogued as COSV51950055, COSV51950478; called by muse, varscan2
- ANKK1 | c.573C>T p.I191= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, varscan2
- ANXA6 | c.192C>T p.S64= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV62905690, COSV62908553; called by muse, mutect2, varscan2
- AOC3 | c.414G>A p.V138= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs748631499, COSV53824456; called by mutect2, varscan2
- AP002512.3 | c.621C>T p.F207= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV54405698; called by mutect2, varscan2
- APBA1 | c.2040C>T p.L680= | Silent (SNP) | VAF 52/96 reads (54%) | catalogued as COSV55222573; called by muse, mutect2, varscan2
- ARHGEF10L | c.1269C>T p.I423= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs1490393518, COSV51428825; called by mutect2, varscan2
- ART4 | c.903C>T p.S301= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV57451143; called by muse, mutect2, varscan2
- ASTN2 | c.1179C>T p.S393= (on ENST00000313400 / NM_001365069.1; = p.S342= on NM_014010.5) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57755159; called by muse, varscan2
- ASXL3 | c.1101G>A p.E367= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV52458037, COSV52458842; called by muse, mutect2, varscan2
- AXDND1 | c.780C>T p.T260= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV62640228; called by muse, mutect2, varscan2
- AZGP1 | c.465C>T p.V155= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV52797143; called by muse, varscan2
- BARX2 | c.198C>T p.S66= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as COSV55649502; called by muse, mutect2, varscan2
- BRINP3 | c.633G>T p.R211= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as COSV66513891, COSV66514865; called by mutect2, varscan2
- CARD8 | c.915C>T p.I305= (on ENST00000651546 / NM_001184900.3; = p.I255= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs751550629, COSV62872908; called by mutect2, varscan2
- CATSPER1 | c.324C>T p.H108= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV56409189; called by muse, mutect2, varscan2
- CBLIF | c.276C>T p.L92= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs761587396, COSV57238130; called by mutect2, varscan2
- CCDC57 | c.552G>A p.K184= | Silent (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- CDIN1 | c.789C>T p.I263= (on ENST00000437989; = p.I165= on NM_032499.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1010226084, COSV57710048; called by muse, mutect2, varscan2
- CEP76 | c.399T>C p.C133= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV50865635; called by muse, mutect2, varscan2
- CETN1 | c.402G>A p.G134= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV59120972; called by muse, mutect2, varscan2
- CFAP94 | c.141G>A p.Q47= (on ENST00000320267 / NM_001352064.2; = p.Q53= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV57230360; called by muse, mutect2, varscan2
- CHAMP1 | c.192C>T p.C64= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs782421881, COSV63521870; called by muse, varscan2
- CITED2 | c.9C>T p.D3= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs148956290, COSV62726271; called by mutect2, varscan2
- CLIC5 | c.618C>T p.V206= (on ENST00000185206 / NM_001370649.1; = p.V47= on NM_016929.5) | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as rs776328726, COSV51755713; called by mutect2, varscan2
- CNTNAP2 | c.3483G>A p.G1161= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV62149926; called by muse, mutect2, varscan2
- COL14A1 | c.1908G>A p.T636= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs1344599321, COSV52848323; called by mutect2, varscan2
- COL4A6 | c.2673C>T p.A891= | Silent (SNP) | VAF 51/69 reads (74%) | catalogued as COSV57860130; called by muse, mutect2, varscan2
- CRAT | c.1242C>T p.F414= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV58876211; called by muse, mutect2, varscan2
- CREBBP | c.2122C>T p.L708= | Silent (SNP) | VAF 58/112 reads (52%) | catalogued as COSV52115443; called by muse, mutect2, varscan2
- CSF3R | c.699G>A p.R233= | Silent (SNP) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- CSMD1 | c.4041G>A p.K1347= (on ENST00000520002; = p.K1346= on NM_033225.6) | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1255668386, COSV59288773, COSV59374130; called by muse, mutect2, varscan2
- CSMD2 | c.7731C>T p.G2577= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV53885149; called by muse, mutect2, varscan2
- CTNNA3 | c.468G>A p.R156= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV57717439; called by muse, mutect2, varscan2
- CTNNBIP1 | c.129C>T p.T43= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV65962071; called by muse, mutect2, varscan2
- CYP4B1 | c.1242G>A p.R414= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV54721572; called by muse, varscan2
- DCDC1 | c.180C>T p.S60= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV60835552; called by muse, mutect2, varscan2
- DELE1 | c.369C>T p.P123= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs1473189508, COSV52003911; called by muse, mutect2, varscan2
- DLGAP4 | c.138C>T p.F46= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV59414995; called by muse, varscan2
- DNAH9 | c.6742C>T p.L2248= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as COSV52337064; called by muse, mutect2, varscan2
- DPYD | c.504C>T p.I168= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as COSV64590229; called by muse, mutect2, varscan2
- DRD3 | c.216T>C p.A72= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs749163990, COSV55678960; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.906G>A p.V302= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV62566910; called by muse, mutect2, varscan2
- ELAPOR2 | c.2175G>A p.K725= (on ENST00000450689 / NM_001142749.3; = p.K558= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs774470956, COSV51884584; called by muse, mutect2, varscan2
- FAM160B2 | c.1809C>T p.F603= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV57157132; called by muse, mutect2, varscan2
- FAM53C | c.519C>T p.L173= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV53510894; called by muse, mutect2, varscan2
- FBP1 | c.699C>T p.F233= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs767551969, COSV64688772; called by mutect2, varscan2
- FGF14 | c.357G>A p.V119= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV65936828; called by mutect2, varscan2
- FIP1L1 | c.1080C>T p.F360= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV60994001; called by muse, mutect2, varscan2
- FN1 | c.3495A>G p.P1165= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV60547717; called by muse, varscan2
- FRMPD2 | c.1005G>A p.G335= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV59715735; called by muse, varscan2
- FYCO1 | c.1446C>T p.S482= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV56114010; called by muse, mutect2, varscan2
- GABRA6 | c.963C>T p.F321= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs148840190, COSV50877940; called by mutect2, varscan2
- GFOD1 | c.585C>T p.V195= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV64954332; called by muse, mutect2, varscan2
- GLI2 | c.3360G>A p.L1120= (on ENST00000361492 / NM_001374353.1; = p.L1137= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV58035767; called by mutect2, varscan2
- GLP1R | c.528G>A p.R176= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs866849283, COSV64714399; called by muse, mutect2, varscan2
- GPR152 | c.594C>T p.V198= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- GPR55 | c.408G>A p.R136= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV67407133; called by muse, mutect2, varscan2
- GPRIN2 | c.828G>A p.V276= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV65400541; called by mutect2, varscan2
- HECTD3 | c.1701C>T p.P567= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV64669758; called by muse, mutect2, varscan2
- HS3ST2 | c.681C>T p.T227= | Silent (SNP) | VAF 67/111 reads (60%) | catalogued as rs764361479, COSV54458866, COSV99758020; called by muse, mutect2, varscan2
- HSPA12B | c.723G>A p.L241= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV54765822; called by muse, mutect2, varscan2
- HTR1E | c.852C>A p.T284= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV100541114, COSV59506919; called by mutect2, varscan2
- IFT140 | c.3399C>T p.F1133= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as rs902953810, COSV63697311; called by mutect2, varscan2
- IGSF22 | c.2631G>A p.V877= (on ENST00000319338; = p.V978= on NM_173588.4) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV55010146; called by mutect2, varscan2
- IRAK3 | c.495C>T p.F165= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV54159438; called by muse, mutect2, varscan2
- KCNG4 | c.558G>A p.Q186= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV57582846; called by muse, mutect2, varscan2
- KCNJ5 | c.621C>T p.V207= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs1254491348, COSV57963685; called by mutect2, varscan2
- KCNT2 | c.1539C>T p.F513= | Silent (SNP) | VAF 121/171 reads (71%) | catalogued as COSV54066659; called by muse, mutect2, varscan2
- KCTD8 | c.1074C>T p.S358= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV63585862; called by muse, mutect2, varscan2
- KIF19 | c.2874G>A p.G958= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1426080249, COSV63428925; called by muse, varscan2
- KLHDC8A | c.516C>T p.L172= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV65678720; called by muse, varscan2
- KRT37 | c.225T>C p.T75= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV56657049; called by muse, mutect2, varscan2
- LAMA2 | c.3588C>T p.P1196= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV70340079; called by muse, mutect2, varscan2
- LRRC23 | c.792C>T p.A264= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV50386928; called by muse, mutect2, varscan2
- MAML3 | c.1734C>T p.I578= | Silent (SNP) | VAF 155/413 reads (38%) | catalogued as COSV59071695; called by muse, mutect2, varscan2
- MATK | c.957G>A p.R319= (on ENST00000310132 / NM_139355.3; = p.R320= on NM_002378.4) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59554771; called by muse, varscan2
- ME1 | c.300T>A p.I100= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV63837853; called by muse, mutect2, varscan2
- MED15 | c.1245C>T p.I415= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV53027200; called by muse, mutect2, varscan2
- MLXIP | c.2085C>T p.S695= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV59834216; called by muse, mutect2, varscan2
- MRGPRX3 | c.108C>T p.I36= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as rs201385722; called by muse, mutect2, varscan2
- MROH2B | c.1056C>T p.I352= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs1193067458, COSV68181714; called by mutect2, varscan2
- MS4A6E | c.160C>T p.L54= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs1463237471, COSV55726268; called by muse, mutect2, varscan2
- MUC16 | c.31494C>T p.V10498= | Silent (SNP) | VAF 130/277 reads (47%) | catalogued as rs867014692, COSV67448903; called by muse, mutect2, varscan2
- MYH14 | c.4236C>T p.R1412= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV51811484; called by muse, mutect2, varscan2
- MYO1C | c.1476G>T p.S492= (on ENST00000648651 / NM_001080779.2; = p.S457= on NM_033375.5) | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV62998496; called by muse, mutect2, varscan2
- NEUROD4 | c.597C>T p.V199= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs774786438, COSV54470704; called by muse, mutect2, varscan2
- NLRP1 | c.1758C>T p.F586= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV52559622; called by mutect2, varscan2
- NLRP3 | c.687G>A p.G229= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV60220849; called by muse, mutect2, varscan2
- NRG3 | c.1569G>A p.T523= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs201130477, COSV64547215; called by mutect2, varscan2
- NRXN1 | c.2841G>A p.G947= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs201264810, COSV58438852, COSV58451846; called by muse, mutect2, varscan2
- NRXN3 | c.504C>T p.A168= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- ODF4 | c.372C>T p.I124= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs537582659, COSV60271721; called by muse, mutect2, varscan2
- OR10H2 | c.648C>T p.L216= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV59945470; called by muse, mutect2, varscan2
- OR10J1 | c.855C>T p.N285= | Silent (SNP) | VAF 68/105 reads (65%) | catalogued as COSV71128270; called by muse, mutect2, varscan2
- OR11G2 | c.618C>T p.F206= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV62131869; called by muse, mutect2, varscan2
- OR13C4 | c.342C>T p.L114= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs1207691866, COSV52925884; called by muse, mutect2, varscan2
- OR13C8 | c.648C>T p.I216= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV58610589, COSV58610602; called by muse, mutect2, varscan2
- OR14I1 | c.873G>A p.R291= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV61199126; called by muse, mutect2, varscan2
- OR1L8 | c.753C>T p.L251= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV59185890; called by muse, mutect2, varscan2
- OR1N2 | c.237C>T p.A79= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as COSV65460273; called by muse, mutect2, varscan2
- OR2K2 | c.903C>T p.I301= (on ENST00000374428; = p.I272= on NM_205859.2) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV57016214; called by mutect2, varscan2
- OR4C12 | c.267C>T p.I89= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as COSV58859504; called by muse, mutect2, varscan2
- OR51B2 | c.528C>T p.F176= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV60916037; called by muse, varscan2
- OR51B4 | c.480C>T p.L160= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs759793130, COSV66516886, COSV66517423; called by muse, varscan2
- OR52L1 | c.534C>T p.P178= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs751914363, COSV59985926; called by muse, mutect2, varscan2
- OR5A2 | c.81C>T p.F27= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV57390483; called by muse, mutect2, varscan2
- OR5W2 | c.912G>A p.L304= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV60614800; called by mutect2, varscan2
- OR5W2 | c.543C>T p.I181= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs755394856, COSV100747766, COSV60614817; called by muse, mutect2, varscan2
- OR6C75 | c.696G>A p.R232= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV58551348; called by muse, mutect2, varscan2
- PAPPA2 | c.2472C>T p.A824= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as rs773129615, COSV62774023; called by muse, varscan2
- PCDHA12 | c.33C>T p.S11= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV56481341; called by muse, mutect2, varscan2
- PCDHB2 | c.1377C>T p.T459= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs17844374, COSV50564771; called by muse, varscan2
- PEAR1 | c.1749G>A p.K583= | Silent (SNP) | VAF 135/189 reads (71%) | catalogued as COSV52771353; called by muse, mutect2, varscan2
- PIK3R4 | c.150C>T p.V50= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs759836189, COSV63239246; called by mutect2, varscan2
- PKD1L1 | c.7056A>T p.G2352= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV51841405; called by mutect2, varscan2
- PLCE1 | c.4875G>A p.K1625= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV53339137; called by muse, mutect2, varscan2
- PLCH1 | c.2787G>A p.R929= (on ENST00000340059 / NM_001130960.2; = p.R921= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV58188939; called by muse, mutect2, varscan2
- PLEKHG4B | c.3609C>T p.S1203= (on ENST00000283426; = p.S1559= on NM_052909.5) | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV52044328; called by muse, mutect2, varscan2
- PLXDC2 | c.231G>A p.T77= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs751339773, COSV65912536, COSV65923103; called by mutect2, varscan2
- PLXNA4 | c.1998G>A p.V666= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs969879267, COSV58108346; called by muse, mutect2, varscan2
- PRRC2B | c.3087C>T p.A1029= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV61934323, COSV61938556; called by muse, varscan2
- RASEF | c.1404G>A p.Q468= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV64586082; called by muse, mutect2, varscan2
- RPN1 | c.1800C>T p.I600= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs142951968; called by muse, mutect2, varscan2
- SCN10A | c.2025C>T p.I675= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs371261235; called by mutect2, varscan2
- SERBP1 | c.39C>G p.V13= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV63413180; called by muse, mutect2, varscan2
- SFTPD | c.648G>A p.K216= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV64852692; called by muse, mutect2, varscan2
- SLC17A8 | c.1500C>T p.V500= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV60122074; called by muse, mutect2, varscan2
- SLC35F4 | c.1464G>A p.K488= (on ENST00000339762 / NM_001352015.2; = p.K452= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV60263061; called by muse, varscan2
- SLC4A1 | c.2721G>C p.V907= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV52258639; called by muse, mutect2, varscan2
- SLC6A3 | c.789G>A p.G263= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV54361979; called by muse, mutect2, varscan2
- SLIT3 | c.1962C>T p.S654= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV60594898; called by muse, mutect2, varscan2
- SLITRK1 | c.447C>T p.A149= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs778556094, COSV65674485; called by muse, mutect2, varscan2
- SLITRK4 | c.768C>A p.T256= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV62022381; called by mutect2, varscan2
- SNTG1 | c.261C>T p.I87= | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as COSV52427838; called by muse, mutect2, varscan2
- SPAM1 | c.114C>T p.F38= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs868194697, COSV56141428; called by mutect2, varscan2
- ST6GAL2 | c.1008G>A p.G336= | Silent (SNP) | VAF 57/170 reads (34%) | catalogued as rs769865559, COSV62415984, COSV62416261; called by muse, mutect2, varscan2
- STAT4 | c.921G>A p.L307= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV61828264; called by muse, mutect2, varscan2
- SYNGR4 | c.522C>T p.V174= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV61225131; called by muse, mutect2, varscan2
- TBCE | c.888C>T p.I296= (on ENST00000366601; = p.I359= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs1439713869, COSV64005298; called by mutect2, varscan2
- TF | c.1191C>T p.I397= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs776533532, COSV53917959, COSV53918224; called by mutect2, varscan2
- THAP4 | c.471G>A p.A157= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs750406019, COSV67190801; called by muse, mutect2, varscan2
- THSD7B | c.1650G>A p.G550= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV55659771, COSV55696616; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.6G>A p.G2= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV59528199; called by muse, mutect2, varscan2
- TOMM40 | c.951T>C p.S317= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV52985088; called by muse, mutect2, varscan2
- TRAV6 | c.291G>A p.R97= | Silent (SNP) | VAF 59/107 reads (55%) | called by muse, mutect2, varscan2
- TRAV8-4 | c.288G>A p.T96= | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as rs267603931; called by mutect2, varscan2
- TRIM33 | c.768C>T p.I256= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV61821104; called by muse, mutect2, varscan2
- TRPM2 | c.4299G>A p.R1433= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs1382513399, COSV55966659; called by muse, mutect2, varscan2
- TRPM4 | c.1320C>T p.F440= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs145772095; called by mutect2, varscan2
- TSPO2 | c.504G>A p.K168= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs533890647, COSV55109156, COSV99770820; called by mutect2, varscan2
- TTN | c.33103C>T p.L11035= (on ENST00000591111; = p.L10108= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV59912282; called by muse, varscan2
- TTN | c.32205G>A p.K10735= (on ENST00000591111; = p.K9808= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as COSV59912289; called by muse, mutect2, varscan2
- TTN | c.20130G>A p.G6710= (on ENST00000591111; = p.G5783= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs777605427, COSV59912298; called by muse, mutect2, varscan2
- UNC13A | c.2514C>T p.V838= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV53189483; called by mutect2, varscan2
- USP8 | c.2535C>T p.I845= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as COSV56162678; called by muse, mutect2, varscan2
- VAV3 | c.948G>A p.G316= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV58377914; called by muse, mutect2, varscan2
- VDAC3 | c.507C>T p.F169= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs767701788, COSV50081274; called by muse, mutect2, varscan2
- VWF | c.7146C>T p.T2382= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV54613079; called by muse, mutect2, varscan2
- WDR38 | c.351G>A p.S117= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs764374218, COSV62160785; called by mutect2, varscan2
- WDR49 | c.1878G>A p.V626= (on ENST00000308378 / NM_001366158.1; = p.V967= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 74/214 reads (35%) | catalogued as COSV57703317; called by mutect2, varscan2
- WFS1 | c.2637C>T p.F879= | Silent (SNP) | VAF 65/164 reads (40%) | catalogued as rs770625544, COSV56987728; called by muse, mutect2, varscan2
- WNT8A | c.475C>T p.L159= | Silent (SNP) | VAF 69/168 reads (41%) | catalogued as COSV64230832, COSV64230836; called by muse, mutect2, varscan2
- ZBED4 | c.45C>T p.F15= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs1181658150, COSV53464049; called by muse, mutect2, varscan2
- ZMYND8 | c.2358C>T p.T786= (on ENST00000311275 / NM_001363741.2; = p.T806= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as rs771098315, COSV53683587; called by muse, mutect2, varscan2
- ZNF143 | c.1230C>T p.V410= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV55178685; called by muse, mutect2, varscan2
- ZNF816 | c.207C>T p.S69= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV54410539; called by muse, mutect2, varscan2
- AGAP7P | n.1634G>A | RNA (SNP) | VAF 39/186 reads (21%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851167 C>T | 3'Flank (SNP) | VAF 100/122 reads (82%) | called by muse, mutect2, varscan2
- BTNL8 | c.787+71C>T | Intron (SNP) | VAF 69/210 reads (33%) | catalogued as COSV99180566; called by muse, mutect2, varscan2
- DEPDC1 | c.911-401C>T | Intron (SNP) | VAF 54/166 reads (33%) | catalogued as COSV100920270; called by muse, mutect2, varscan2
- NEBL | c.164+46513G>A | Intron (SNP) | VAF 63/150 reads (42%) | catalogued as COSV65797883, COSV65797895; called by muse, varscan2
- SNORD116-29 | n.72G>A | RNA (SNP) | VAF 22/49 reads (45%) | catalogued as rs1335029856; called by muse, mutect2, varscan2
- TBC1D29P | n.2698G>A | RNA (SNP) | VAF 14/47 reads (30%) | catalogued as COSV70433888; called by muse, mutect2, varscan2
- TCF7L2 | c.552+49392T>C | Intron (SNP) | VAF 65/184 reads (35%) | catalogued as rs1432549304, COSV60501335; called by muse, mutect2, varscan2
- TTN | c.10360+5124G>A | Intron (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
